Somatic mutation profile of tumor specimen TCGA-51-4080-01A (aliquot TCGA-51-4080-01A-01D-1458-08) from TCGA case TCGA-51-4080, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 65.9 years (24,054 days).
Specimen TCGA-51-4080-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33c2e9e5-3ac6-4f42-8877-88a7ea53717f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-51-4080-11A (Solid Tissue Normal), aliquot TCGA-51-4080-11A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82cb8f45-156c-4f71-9208-bb060819bf1c

The open-access MAF lists 308 somatic variants for this specimen: 245 protein-altering or splice-affecting, 56 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 56, Nonsense Mutation 19, Splice Site 8, Frame Shift Del 7, Splice Region 3, 5'Flank 3, RNA 2, In Frame Del 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 35/74 reads (47%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, mutect2, varscan2
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 25/29 reads (86%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3227C>G p.A1076G (on ENST00000272895 / NM_173076.3; = p.A758G on NM_015657.3) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55955756, COSV55957871; called by muse, mutect2, varscan2
- ABI1 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV61016732; called by muse, mutect2, varscan2
- ABI1 | c.478-1G>T p.X160_splice | Splice Site (SNP) | VAF 45/61 reads (74%) | catalogued as COSV61016742; called by muse, mutect2, varscan2
- ADAMTS18 | c.2412G>T p.W804C | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51407821, COSV51419415; called by muse, mutect2, varscan2
- ADAMTS7 | c.3812C>T p.A1271V | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV66307069; called by muse, varscan2
- ADGRB3 | c.1322G>A p.W441* | Nonsense Mutation (SNP) | VAF 36/85 reads (42%) | catalogued as COSV65393597; called by muse, mutect2, varscan2
- AMTN | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59488907; called by muse, mutect2, varscan2
- ANKFN1 | c.2056G>T p.A686S | Missense Mutation (SNP) | VAF 354/618 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV59446621; called by muse, mutect2, varscan2
- APOB | c.9704C>A p.A3235D | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV51934137; called by muse, mutect2, varscan2
- ARID1B | c.4993G>T p.G1665* | Nonsense Mutation (SNP) | VAF 322/807 reads (40%) | catalogued as rs1554237010, COSV51660265; called by muse, varscan2
- ARID1B | c.5279A>C p.D1760A | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV51660276; called by muse, mutect2, varscan2
- ARRB1 | c.1151A>T p.D384V | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV63575325; called by muse, mutect2, varscan2
- ASTN2 | c.1683G>T p.W561C (on ENST00000313400 / NM_001365069.1; = p.W510C on NM_014010.5) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57774684; called by muse, mutect2, varscan2
- ATP8A1 | c.1253T>A p.V418E | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV52534093; called by muse, mutect2, varscan2
- ATP8A2 | c.2771C>G p.P924R | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54950143, COSV99029392; called by muse, mutect2, varscan2
- AXIN2 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs760625400, COSV61057389, COSV61059584; called by muse, varscan2
- BLZF1 | c.754A>T p.S252C | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV61393462; called by muse, mutect2, varscan2
- BPTF | c.5686A>G p.R1896G | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV58836543; called by muse, mutect2, varscan2
- BRINP3 | c.2002G>T p.V668L | Missense Mutation (SNP) | VAF 89/310 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV66523075; called by muse, mutect2, varscan2
- CADPS2 | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV57361674; called by muse, mutect2
- CARD6 | c.3092A>T p.Q1031L | Missense Mutation (SNP) | VAF 148/361 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54565969; called by muse, mutect2, varscan2
- CARMIL2 | c.4180C>G p.P1394A | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV54667440; called by muse, mutect2, varscan2
- CCDC141 | c.2350G>C p.D784H | Missense Mutation (SNP) | VAF 102/262 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV55373017; called by muse, mutect2, varscan2
- CCDC39 | c.1238C>A p.T413K | Missense Mutation (SNP) | VAF 218/447 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56483426; called by muse, mutect2, varscan2
- CD1C | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV63806350; called by muse, mutect2, varscan2
- CD207 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as COSV69651999; called by muse, mutect2, varscan2
- CD33 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51801527; called by muse, mutect2, varscan2
- CDH18 | c.675C>G p.D225E | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56919569, COSV56921805; called by muse, mutect2, varscan2
- CDH3 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 101/224 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50557294; called by muse, mutect2, varscan2
- CDH5 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs767005229, COSV58516262, COSV58517064; called by muse, mutect2, varscan2
- CDH6 | c.415G>C p.V139L | Missense Mutation (SNP) | VAF 129/278 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV54069108; called by muse, mutect2, varscan2
- CDH9 | c.1436T>A p.L479Q | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50278790; called by muse, mutect2, varscan2
- CEP112 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 149/246 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV67138982; called by muse, mutect2, varscan2
- CFHR5 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 100/350 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777208363, COSV56821513; called by muse, mutect2, varscan2
- CHTF18 | c.2618C>A p.P873Q | Missense Mutation (SNP) | VAF 105/126 reads (83%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV50210137, COSV50210395; called by muse, mutect2, varscan2
- CLVS1 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57974415; called by muse, mutect2, varscan2
- CNGA4 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV66005834; called by muse, mutect2, varscan2
- CNGB3 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 246/499 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV60684144, COSV60689104; called by muse, mutect2, varscan2
- CNTN1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV61639338, COSV61642540; called by muse, mutect2, varscan2
- CNTN5 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 106/226 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV54307565, COSV99671966; called by muse, mutect2, varscan2
- CNTN5 | c.2417G>T p.G806V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54307583; called by muse, varscan2
- COG7 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV56150189; called by muse, mutect2, varscan2
- COL20A1 | c.1753C>A p.R585S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV58916583, COSV58919462; called by muse, mutect2, varscan2
- COL2A1 | c.3929C>G p.A1310G | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61530229; called by muse, mutect2, varscan2
- COL4A2 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64627883; called by muse, mutect2
- COL5A2 | c.4171C>T p.R1391C | Missense Mutation (SNP) | VAF 111/198 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759098736, COSV66409370; called by muse, mutect2, varscan2
- COL6A3 | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs748053172, COSV55081138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPS1 | c.1576C>T p.L526F | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0.372); catalogued as rs775632596, COSV51809054; called by muse, mutect2, varscan2
- CSMD3 | c.4411G>T p.V1471F (on ENST00000297405 / NM_001363185.1; = p.V1367F on NM_052900.3) | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV52143931, COSV52170253; called by muse, mutect2, varscan2
- CYB5R1 | c.15G>A p.T5= | Splice Region (SNP) | VAF 17/55 reads (31%) | catalogued as rs199856907; called by muse, mutect2, varscan2
- CYP11B1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 85/153 reads (56%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.942); catalogued as COSV52826798; called by muse, mutect2, varscan2
- CYP4F2 | c.1424T>A p.M475K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55617782; called by muse, varscan2
- DCANP1 | c.219C>G p.N73K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); catalogued as rs760625228, COSV72345801; called by muse, mutect2
- DLC1 | c.2794G>A p.D932N (on ENST00000276297 / NM_001348081.2; = p.D495N on NM_006094.5) | Missense Mutation (SNP) | VAF 77/101 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV52302224; called by muse, mutect2, varscan2
- DNAH10 | c.5579T>C p.M1860T (on ENST00000409039; = p.M1799T on NM_207437.3) | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV68992954; called by muse, mutect2, varscan2
- DNER | c.1740T>G p.I580M | Missense Mutation (SNP) | VAF 124/313 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100519097, COSV59165379; called by muse, mutect2, varscan2
- DPPA3 | c.364G>T p.V122F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.201); catalogued as COSV61502997; called by muse, mutect2, varscan2
- E4F1 | c.361G>C p.V121L | Missense Mutation (SNP) | VAF 175/201 reads (87%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs756118944, COSV57038883; called by muse, mutect2, varscan2
- ECD | c.719C>G p.P240R | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65899698; called by muse, mutect2, varscan2
- EEF1AKNMT | c.310G>C p.D104H (on ENST00000361735 / NM_015935.5; = p.D18H on NM_014955.3) | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62282975; called by muse, mutect2, varscan2
- EMILIN3 | c.1930C>A p.L644I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV60036058; called by muse, mutect2, varscan2
- ENTPD7 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as COSV65112244; called by muse, mutect2, varscan2
- EPB41L3 | c.1162A>T p.R388* | Nonsense Mutation (SNP) | VAF 101/263 reads (38%) | catalogued as COSV59452108; called by muse, mutect2, varscan2
- EPHA5 | c.2216T>C p.L739S | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358001965, COSV56643307, COSV56677759; called by muse, mutect2, varscan2
- ERC1 | c.456G>T p.M152I | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV61694478; called by muse, mutect2, varscan2
- ERC1 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057436515, COSV61694482; called by muse, mutect2, varscan2
- FAM135B | c.4095C>A p.N1365K | Missense Mutation (SNP) | VAF 198/669 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52722286; called by muse, mutect2, varscan2
- FAM135B | c.2347G>T p.A783S | Missense Mutation (SNP) | VAF 88/153 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV52722297; called by muse, mutect2, varscan2
- FAM171B | c.2452G>T p.E818* | Nonsense Mutation (SNP) | VAF 36/81 reads (44%) | catalogued as COSV59003088; called by muse, mutect2, varscan2
- FAM220A | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV57626308; called by muse, mutect2, varscan2
- FAM47C | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs781942309, COSV100792267, COSV63726287; called by muse, mutect2, varscan2
- FAM47C | c.3081C>A p.D1027E | Missense Mutation (SNP) | VAF 107/122 reads (88%) | SIFT tolerated (0.29); PolyPhen benign (0.242); catalogued as rs1436231139, COSV63725964, COSV63726299; called by muse, mutect2, varscan2
- FAM76B | c.85A>C p.K29Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV57688270; called by muse, mutect2
- FBN1 | c.7702G>T p.V2568L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as CM077254, COSV57315678; called by muse, mutect2, varscan2
- FBXO44 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 62/83 reads (75%) | SIFT tolerated (0.26); PolyPhen benign (0.404); catalogued as rs567768918, COSV52354130; called by muse, mutect2, varscan2
- FN1 | c.5536G>T p.V1846F | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV60551973; called by muse, varscan2
- FRAS1 | c.7536G>C p.L2512F | Missense Mutation (SNP) | VAF 139/412 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV53607602; called by muse, mutect2, varscan2
- FRAS1 | c.7537G>T p.G2513W | Missense Mutation (SNP) | VAF 143/415 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53607621; called by muse, mutect2, varscan2
- FREM1 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 81/178 reads (46%) | catalogued as rs1314812757, COSV101083785, COSV66522846; called by muse, mutect2, varscan2
- FRMPD1 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs540607464, COSV66700241; called by muse, mutect2, varscan2
- FSCB | c.1718C>A p.P573H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61217860; called by muse, mutect2, varscan2
- FUS | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV54216900; called by muse, varscan2
- GABRR1 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65619342; called by muse, mutect2, varscan2
- GBA3 | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.384); catalogued as COSV72438088; called by muse, mutect2, varscan2
- GC | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV56737106; called by muse, mutect2, varscan2
- GLYR1 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 127/151 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV52167852; called by muse, mutect2, varscan2
- GPNMB | c.1327C>T p.P443S (on ENST00000381990 / NM_001005340.2; = p.P431S on NM_002510.3) | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs889460603, COSV51698234; called by muse, mutect2, varscan2
- GPRIN3 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 119/294 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV60884391; called by muse, mutect2, varscan2
- GRIN3A | c.2593G>T p.G865W | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62453105, COSV62453243; called by muse, mutect2, varscan2
- GTDC1 | c.776A>C p.H259P | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV53993947; called by muse, mutect2, varscan2
- HCN1 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 105/248 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV57508108; called by muse, mutect2, varscan2
- HDGF | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 715/1189 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV61976065; called by muse, mutect2, varscan2
- HIC2 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV68042050; called by muse, mutect2, varscan2
- HK3 | c.1972G>A p.V658I | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.843); catalogued as COSV52839666; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV61255276; called by muse, mutect2, varscan2
- HSF2 | c.1297A>C p.K433Q | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.141); catalogued as COSV63773853; called by muse, mutect2, varscan2
- ICOS | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs948265313, COSV57029811; called by muse, mutect2, varscan2
- INTS6 | c.1959C>G p.I653M | Missense Mutation (SNP) | VAF 172/375 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.321); catalogued as COSV60877906, COSV60878121; called by muse, mutect2, varscan2
- ITSN1 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 25/50 reads (50%) | catalogued as COSV66082833; called by muse, mutect2, varscan2
- JAK1 | c.2281C>T p.P761S | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61090678; called by muse, mutect2
- JAK3 | c.3241A>T p.S1081C | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV71686022; called by muse, mutect2, varscan2
- JARID2 | c.2952+2T>A p.X984_splice | Splice Site (SNP) | VAF 43/94 reads (46%) | catalogued as COSV59188899; called by muse, mutect2, varscan2
- KCNQ5 | c.489+1G>C p.X163_splice | Splice Site (SNP) | VAF 74/157 reads (47%) | catalogued as COSV59658799; called by muse, mutect2, varscan2
- KIDINS220 | c.504+1G>A p.X168_splice | Splice Site (SNP) | VAF 37/143 reads (26%) | catalogued as COSV56753001; called by muse, mutect2, varscan2
- KIF16B | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 97/223 reads (43%) | catalogued as COSV61701566, COSV61705644; called by muse, mutect2, varscan2
- KIF1A | c.4826G>C p.R1609P (on ENST00000320389 / NM_001379639.1; = p.R1601P on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57488181; called by muse, mutect2, varscan2
- KIF1B | c.3680C>A p.S1227Y (on ENST00000377086 / NM_001365952.1; = p.S1181Y on NM_015074.3) | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55808206; called by muse, mutect2, varscan2
- KIF20B | c.5388T>A p.I1796= (on ENST00000371728 / NM_001284259.2; = p.I1756= on NM_016195.4) | Splice Region (SNP) | VAF 44/59 reads (75%) | catalogued as COSV53306419; called by muse, mutect2, varscan2
- KLHL1 | c.932C>A p.P311Q | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64771832; called by muse, mutect2, varscan2
- KLHL4 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs751855180, COSV64141978; called by muse, mutect2, varscan2
- KLRB1 | c.441C>A p.D147E | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57589662; called by muse, mutect2, varscan2
- LCP1 | c.833T>A p.L278Q | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59940874; called by muse, mutect2, varscan2
- LILRA2 | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV52191142; called by muse, mutect2, varscan2
- LRFN5 | c.1015A>T p.N339Y | Missense Mutation (SNP) | VAF 95/237 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53254659; called by muse, mutect2, varscan2
- LRRC4C | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV53421587, COSV53424684; called by muse, mutect2, varscan2
- LRRC7 | c.3331C>A p.P1111T (on ENST00000651989 / NM_001370785.2; = p.P1078T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/51 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50450530; called by muse, mutect2, varscan2
- LRRTM3 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 118/144 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63664806; called by muse, mutect2, varscan2
- LUC7L3 | c.338A>C p.Q113P | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.815); catalogued as COSV53586767; called by muse, varscan2
- MAP4K2 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53642962; called by muse, mutect2, varscan2
- MGST1 | c.17A>T p.Q6L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV50566675; called by muse, mutect2, varscan2
- MRPS9 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV51519355; called by muse, mutect2, varscan2
- MS4A8 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV55754110; called by muse, varscan2
- MSANTD4 | c.487A>G p.M163V | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV57285726; called by muse, mutect2, varscan2
- MYCBP2 | c.4297C>T p.R1433C (on ENST00000357337; = p.R1471C on NM_015057.5) | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1383535643, COSV62017602; called by muse, mutect2, varscan2
- MYO15A | c.7682A>G p.Y2561C | Missense Mutation (SNP) | VAF 64/76 reads (84%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV52756097; called by muse, mutect2, varscan2
- MYO7A | c.6394G>A p.A2132T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60019099; called by muse, mutect2
- NALCN | c.2535G>T p.R845S | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV51933348; called by muse, mutect2, varscan2
- NALCN | c.2534G>T p.R845M | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV51933359; called by muse, mutect2, varscan2
- NDST4 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52118327; called by muse, mutect2, varscan2
- NPAT | c.1466C>A p.S489Y | Missense Mutation (SNP) | VAF 148/344 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV53717872; called by muse, mutect2, varscan2
- NTHL1 | c.548G>A p.R183K (on ENST00000219066; = p.R175K on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT tolerated (0.95); PolyPhen benign (0.086); catalogued as COSV54592892; called by muse, mutect2, varscan2
- NXPH1 | c.190C>A p.R64S | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV68311661, COSV68314277; called by muse, mutect2, varscan2
- OR11H12 | c.832G>T p.G278* | Nonsense Mutation (SNP) | VAF 63/189 reads (33%) | catalogued as COSV101612539; called by mutect2, varscan2
- OR11L1 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV63314335; called by muse, mutect2, varscan2
- OR13G1 | c.351T>G p.Y117* | Nonsense Mutation (SNP) | VAF 38/126 reads (30%) | catalogued as COSV62944069; called by muse, mutect2, varscan2
- OR14A16 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 114/360 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV62926184, COSV62926588; called by muse, mutect2, varscan2
- OR1C1 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV68715700; called by muse, mutect2, varscan2
- OR2L13 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 82/144 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63552430; called by muse, mutect2, varscan2
- OR2M5 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 459/779 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV63546190; called by muse, mutect2, varscan2
- OR2T33 | c.110T>A p.L37Q | Missense Mutation (SNP) | VAF 98/410 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58815238; called by muse, varscan2
- OR4D2 | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 241/381 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV73459755; called by muse, mutect2, varscan2
- OR4M1 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 182/414 reads (44%) | catalogued as COSV60061130; called by muse, mutect2, varscan2
- OR52E4 | c.270C>A p.N90K | Missense Mutation (SNP) | VAF 118/246 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57624644; called by muse, mutect2, varscan2
- OR5D14 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV59456171; called by muse, mutect2, varscan2
- OR5T2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 117/292 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs1276578450, COSV57588995; called by muse, mutect2, varscan2
- OTOF | c.3349G>T p.G1117C (on ENST00000272371 / NM_194248.3; = p.G370C on NM_004802.4) | Missense Mutation (SNP) | VAF 127/206 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55502169; called by muse, mutect2, varscan2
- OXCT1 | c.413A>T p.Q138L | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52170506; called by muse, mutect2, varscan2
- PAPLN | c.1092G>A p.K364= (on ENST00000554301; = p.K337= on NM_173462.4) | Splice Region (SNP) | VAF 22/208 reads (11%) | catalogued as rs765949524, COSV53717329; called by muse, mutect2, varscan2
- PCDH12 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as rs746450107, COSV51521150; called by muse, mutect2, varscan2
- PDE1B | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 105/221 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV54492497; called by muse, mutect2, varscan2
- PDE2A | c.2779G>A p.G927S | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV57806192; called by muse, mutect2, varscan2
- PDE9A | c.1338C>A p.N446K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV52325544; called by muse, mutect2, varscan2
- PDHA2 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375415371, COSV54778953; called by muse, mutect2, varscan2
- PDLIM5 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs771478401, COSV58747523; called by muse, mutect2, varscan2
- PKNOX1 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52335781; called by muse, mutect2, varscan2
- PLCH1 | c.904G>A p.D302N (on ENST00000340059 / NM_001130960.2; = p.D314N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV58195886; called by muse, mutect2, varscan2
- PLXNA4 | c.1987C>A p.L663M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.937); catalogued as COSV58122800; called by muse, mutect2, varscan2
- POLR3H | c.289G>C p.V97L | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV53442630; called by muse, mutect2, varscan2
- POTEH | c.308G>C p.C103S | Missense Mutation (SNP) | VAF 211/884 reads (24%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.152); catalogued as rs561314696, COSV100625298; called by muse, varscan2
- PPFIA2 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61030769; called by muse, mutect2, varscan2
- PRPF40A | c.2482C>T p.R828* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1194895248, COSV68357225; called by muse, mutect2, varscan2
- QRICH2 | c.2157_2186del p.M720_G729del | In Frame Del (DEL) | VAF 67/219 reads (31%) | catalogued as rs778377799; called by muse*, mutect2
- RICTOR | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV57121447; called by muse, mutect2, varscan2
- RIMS1 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as COSV53453824; called by muse, mutect2, varscan2
- RP1 | c.1373G>C p.R458T | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV55115968; called by muse, mutect2, varscan2
- RXFP3 | c.960A>T p.R320S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100347668, COSV57505402; called by muse, mutect2, varscan2
- RYR2 | c.6754G>A p.E2252K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1318607228, COSV63683396; called by muse, mutect2
- RYR2 | c.11270C>T p.A3757V | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV63683399; called by muse, mutect2, varscan2
- RYR2 | c.11813G>A p.S3938N | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63683402; called by muse, mutect2, varscan2
- SALL3 | c.216C>A p.S72R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV73306018; called by muse, mutect2, varscan2
- SCAP | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 116/137 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55561039; called by muse, mutect2, varscan2
- SCN7A | c.629C>G p.T210S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV69271186, COSV69271788; called by muse, mutect2, varscan2
- SELENOT | c.109A>T p.T37S | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV101517717, COSV72000375; called by muse, mutect2, varscan2
- SH2D3C | c.194C>G p.P65R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.172); catalogued as COSV59122267; called by muse, mutect2, varscan2
- SHANK1 | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV53249528; called by muse, mutect2, varscan2
- SLC12A1 | c.1582T>A p.Y528N | Missense Mutation (SNP) | VAF 70/133 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66794479; called by muse, mutect2, varscan2
- SLC17A3 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57759917; called by muse, mutect2, varscan2
- SLC17A6 | c.1453C>A p.L485I | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV54136032; called by muse, mutect2, varscan2
- SLC44A5 | c.74C>A p.P25Q | Missense Mutation (SNP) | VAF 283/341 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV63764010; called by muse, mutect2, varscan2
- SLC45A2 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as HM0681, COSV56871508; called by muse, mutect2, varscan2
- SLITRK6 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 260/661 reads (39%) | catalogued as COSV68390094; called by muse, mutect2, varscan2
- SPATA22 | c.838T>G p.Y280D | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV52152485; called by muse, mutect2, varscan2
- SPDYE3 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1197586962, COSV60107160; called by muse, mutect2, varscan2
- SPEF2 | c.3064del p.X1022_splice | Splice Site (DEL) | VAF 53/157 reads (34%) | catalogued as COSV61548962; called by mutect2, pindel, varscan2
- SPHKAP | c.2918A>T p.N973I | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV60877468; called by muse, varscan2
- SPOCK2 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV58036332; called by muse, mutect2, varscan2
- STX19 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV57398062; called by muse, mutect2, varscan2
- TAF1L | c.2785G>T p.A929S | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as COSV54261470; called by muse, mutect2, varscan2
- TBXT | c.1142C>A p.A381E | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs764888773, COSV51617655, COSV99752710; called by muse, mutect2, varscan2
- TCTN1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1043058821, COSV66541075; called by muse, mutect2, varscan2
- TENM3 | c.6253G>T p.G2085C | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101305538; called by muse, mutect2
- TEPSIN | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56142624; called by muse, mutect2, varscan2
- TG | c.7478C>G p.A2493G | Missense Mutation (SNP) | VAF 205/604 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV55074719; called by muse, mutect2, varscan2
- TMEM107 | c.166G>T p.A56S (on ENST00000437139 / NM_183065.4; = p.A62S on NM_032354.5) | Missense Mutation (SNP) | VAF 74/88 reads (84%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100328868, COSV57101280; called by muse, mutect2, varscan2
- TMEM132D | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67160201; called by muse, mutect2, varscan2
- TMEM170B | c.149A>G p.H50R | Missense Mutation (SNP) | VAF 225/538 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748887674, COSV65157448; called by muse, mutect2, varscan2
- TMTC4 | c.1165G>T p.G389* (on ENST00000376234 / NM_001350577.2; = p.G408* on NM_032813.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV60892072; called by muse, mutect2
- TNN | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53425573; called by muse, mutect2, varscan2
- TNNI3 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV52571670; called by muse, mutect2, varscan2
- TNR | c.3793+1G>C p.X1265_splice | Splice Site (SNP) | VAF 105/171 reads (61%) | catalogued as COSV54883738; called by muse, mutect2, varscan2
- TNS2 | c.2648G>A p.G883D (on ENST00000314250 / NM_170754.4; = p.G893D on NM_015319.2) | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.084); catalogued as rs1177521882, COSV56853695; called by muse, mutect2, varscan2
- TP53RK | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 123/281 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64508922; called by muse, mutect2, varscan2
- TPTE | c.1623G>A p.M541I (on ENST00000618007 / NM_199261.4; = p.M523I on NM_199259.4) | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs758305832; called by muse, mutect2, varscan2
- TRAV17 | c.325T>C p.C109R | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs910344206; called by muse, mutect2, varscan2
- TRIM21 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1434621501, COSV54344002; called by muse, mutect2, varscan2
- TTN | c.96011T>C p.I32004T (on ENST00000591111; = p.I24580T on NM_003319.4) | Missense Mutation (SNP) | VAF 142/325 reads (44%) | PolyPhen probably damaging (0.996); catalogued as COSV60031391; called by muse, mutect2, varscan2
- TTN | c.87055C>T p.R29019W (on ENST00000591111; = p.R21595W on NM_003319.4) | Missense Mutation (SNP) | VAF 56/127 reads (44%) | PolyPhen probably damaging (0.999); catalogued as rs377464325; called by muse, mutect2, varscan2
- TTN | c.36856G>A p.G12286R (on ENST00000591111; = p.G4862R on NM_003319.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | PolyPhen probably damaging (1); catalogued as rs758326922, COSV60031482; called by muse, mutect2, varscan2
- TTN | c.14351C>G p.T4784S (on ENST00000591111; = p.T3857S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/235 reads (43%) | PolyPhen probably damaging (0.994); catalogued as COSV60031544, COSV60167659; called by muse, mutect2, varscan2
- UBA3 | c.730A>T p.R244W | Missense Mutation (SNP) | VAF 80/109 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62740372; called by muse, mutect2, varscan2
- UBE2J1 | c.45A>T p.L15F | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70561334; called by muse, mutect2, varscan2
- UGT2A2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.709); catalogued as rs760361931, COSV99685012; called by muse, mutect2, varscan2
- USH2A | c.6890C>T p.A2297V | Missense Mutation (SNP) | VAF 95/289 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as rs1459792785, COSV56364378; called by muse, mutect2, varscan2
- USP40 | c.326A>G p.Q109R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as rs981753009, COSV52480216; called by muse, mutect2, varscan2
- VN1R4 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV60804921; called by muse, mutect2, varscan2
- VRK2 | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.118); catalogued as COSV60876398; called by mutect2, varscan2
- VWCE | c.1517G>C p.R506P | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV57112277, COSV57114004; called by muse, mutect2
- WDR55 | c.380+2T>C p.X127_splice | Splice Site (SNP) | VAF 99/207 reads (48%) | catalogued as COSV64225748; called by muse, mutect2, varscan2
- WDR92 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV54561313; called by muse, mutect2, varscan2
- WEE2 | c.248C>A p.T83N | Missense Mutation (SNP) | VAF 157/352 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV66878773, COSV66879763; called by muse, mutect2, varscan2
- WFIKKN2 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 62/97 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV60958605; called by muse, mutect2, varscan2
- XIRP2 | c.5140G>T p.D1714Y (on ENST00000628543; = p.D1889Y on NM_152381.6) | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV54697791; called by muse, varscan2
- XIRP2 | c.5188G>C p.A1730P (on ENST00000628543; = p.A1905P on NM_152381.6) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV54697801; called by muse, varscan2
- XKR9 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68772877; called by muse, mutect2, varscan2
- ZBED9 | c.3092C>G p.S1031C | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.423); catalogued as COSV71729383; called by muse, mutect2, varscan2
- ZNF236 | c.2656G>T p.V886L | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV53487444; called by muse, mutect2, varscan2
- ZNF385B | c.476C>A p.T159K | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1388029777, COSV61177527; called by muse, mutect2, varscan2
- ZNF512 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 98/358 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.192); catalogued as COSV62675327; called by muse, mutect2, varscan2
- ZNF518B | c.1724A>G p.N575S | Missense Mutation (SNP) | VAF 106/257 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV58722372; called by muse, mutect2, varscan2
- ZNF615 | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV65033057; called by muse, mutect2, varscan2
- ZNF682 | c.752A>T p.H251L | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62066942; called by muse, mutect2, varscan2
- ZSCAN1 | c.768C>A p.D256E | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV56604113; called by muse, mutect2, varscan2
- ALG13 | c.2012del p.P671Rfs*36 | Frame Shift Del (DEL) | VAF 30/42 reads (71%) | called by mutect2, pindel, varscan2
- ARHGAP9 | c.447_475del p.S149Rfs*35 | Frame Shift Del (DEL) | VAF 74/224 reads (33%) | called by mutect2, pindel, varscan2
- ARID1A | c.1323del p.M442Wfs*177 | Frame Shift Del (DEL) | VAF 40/61 reads (66%) | called by mutect2, pindel, varscan2
- DIPK1B | c.425dup p.P143Afs*40 | Frame Shift Ins (INS) | VAF 34/98 reads (35%) | called by mutect2, pindel, varscan2
- MAGI1 | c.1547-6_1559del p.X516_splice | Splice Site (DEL) | VAF 24/35 reads (69%) | called by mutect2, pindel, varscan2
- MEGF8 | c.3192del p.A1065Pfs*28 (on ENST00000251268 / NM_001271938.2; = p.A998Pfs*28 on NM_001410.3) | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- NCEH1 | c.991del p.L331Sfs*53 (on ENST00000538775; = p.L291Sfs*53 on NM_020792.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 33/263 reads (13%) | called by mutect2, pindel, varscan2
- OR2T3 | c.79A>T p.K27* | Nonsense Mutation (SNP) | VAF 60/343 reads (17%) | called by muse, mutect2
- SLC17A8 | c.847_849del p.E283del | In Frame Del (DEL) | VAF 26/82 reads (32%) | called by pindel, varscan2
- WDR6 | c.2382_2387delinsA p.Q795Rfs*14 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by pindel, varscan2*
- ZFP36L1 | c.654_667del p.L219Hfs*13 | Frame Shift Del (DEL) | VAF 63/183 reads (34%) | called by mutect2, pindel, varscan2
- ABCB4 | c.3504C>A p.P1168= (on ENST00000265723 / NM_018849.3; = p.P1161= on NM_000443.4) | Silent (SNP) | VAF 98/248 reads (40%) | catalogued as COSV55934808; called by muse, mutect2, varscan2
- ACTRT3 | c.804C>A p.A268= | Silent (SNP) | VAF 204/463 reads (44%) | catalogued as COSV57754323; called by muse, mutect2, varscan2
- ANKRD28 | c.843A>G p.A281= | Silent (SNP) | VAF 99/113 reads (88%) | catalogued as COSV67517886; called by muse, mutect2, varscan2
- APBB1 | c.1338C>G p.P446= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV54975420; called by muse, mutect2, varscan2
- ASCC3 | c.4287G>A p.E1429= | Silent (SNP) | VAF 56/132 reads (42%) | catalogued as COSV64974787; called by muse, mutect2, varscan2
- ATP10A | c.4194A>T p.P1398= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV63516886; called by muse, mutect2, varscan2
- AXIN2 | c.240G>A p.K80= | Silent (SNP) | VAF 78/276 reads (28%) | catalogued as COSV61057383; called by muse, varscan2
- BEND4 | c.615C>T p.G205= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV72469080; called by muse, mutect2, varscan2
- BRCA2 | c.5673A>T p.A1891= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV66453156; called by muse, mutect2, varscan2
- BTN2A2 | c.966A>T p.T322= | Silent (SNP) | VAF 136/364 reads (37%) | catalogued as COSV61857282; called by muse, mutect2, varscan2
- CDH9 | c.255T>C p.D85= | Silent (SNP) | VAF 88/197 reads (45%) | catalogued as rs149377000; called by muse, mutect2, varscan2
- CETN3 | c.114T>C p.D38= | Silent (SNP) | VAF 47/58 reads (81%) | catalogued as COSV51617237; called by muse, mutect2, varscan2
- COL20A1 | c.1752G>T p.V584= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV58916564; called by muse, mutect2, varscan2
- CSN3 | c.405T>C p.N135= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV59244026; called by muse, mutect2, varscan2
- DSTYK | c.2695T>C p.L899= | Silent (SNP) | VAF 224/374 reads (60%) | catalogued as COSV65686361; called by muse, mutect2, varscan2
- F5 | c.120C>T p.G40= | Silent (SNP) | VAF 100/167 reads (60%) | catalogued as COSV55251487; called by muse, mutect2, varscan2
- FCGBP | c.828G>T p.L276= | Silent (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- GALR3 | c.339G>A p.L113= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV50763972; called by muse, mutect2, varscan2
- GRIN3A | c.2592G>T p.V864= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV62453251; called by muse, mutect2, varscan2
- GSPT2 | c.1869G>A p.L623= | Silent (SNP) | VAF 41/48 reads (85%) | catalogued as COSV61214245; called by muse, mutect2, varscan2
- HAVCR2 | c.36G>T p.L12= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV57152872; called by muse, mutect2, varscan2
- IGSF9 | c.735A>G p.S245= | Silent (SNP) | VAF 97/147 reads (66%) | catalogued as rs747043750, COSV63639953; called by muse, mutect2, varscan2
- KCTD8 | c.978A>T p.I326= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV63588722; called by muse, mutect2, varscan2
- LAMC3 | c.1197C>A p.G399= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV63090837; called by muse, mutect2, varscan2
- LRIF1 | c.312A>G p.S104= | Silent (SNP) | VAF 88/101 reads (87%) | catalogued as COSV63897279; called by muse, mutect2, varscan2
- MAGEA12 | c.651T>C p.P217= | Silent (SNP) | VAF 147/162 reads (91%) | catalogued as COSV63294745; called by muse, mutect2, varscan2
- MPP7 | c.1242T>A p.G414= | Silent (SNP) | VAF 48/68 reads (71%) | catalogued as COSV61732056; called by muse, mutect2, varscan2
- MSTO1 | c.30A>G p.T10= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as rs754852654, COSV99824435; called by muse, mutect2, varscan2
- MUC16 | c.1872C>A p.T624= | Silent (SNP) | VAF 63/147 reads (43%) | catalogued as COSV67463227; called by muse, mutect2, varscan2
- NR0B1 | c.909C>T p.R303= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as COSV66764044; called by muse, mutect2, varscan2
- NUDT21 | c.300A>T p.G100= | Silent (SNP) | VAF 66/149 reads (44%) | catalogued as COSV55859839; called by muse, mutect2, varscan2
- NUP155 | c.816G>T p.T272= (on ENST00000231498 / NM_153485.3; = p.T213= on NM_004298.4) | Silent (SNP) | VAF 84/190 reads (44%) | catalogued as COSV51529635; called by muse, mutect2, varscan2
- NYNRIN | c.744G>T p.G248= | Silent (SNP) | VAF 63/149 reads (42%) | catalogued as COSV66842275; called by muse, mutect2, varscan2
- OR2A2 | c.852G>T p.L284= | Silent (SNP) | VAF 141/356 reads (40%) | catalogued as COSV68871542; called by muse, mutect2, varscan2
- OR2C3 | c.549C>A p.P183= | Silent (SNP) | VAF 56/80 reads (70%) | catalogued as COSV63574995; called by muse, mutect2, varscan2
- OR2T4 | c.1023T>A p.P341= | Silent (SNP) | VAF 107/333 reads (32%) | catalogued as COSV63543907; called by muse, mutect2, varscan2
- OR3A1 | c.688C>A p.R230= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV60162824, COSV60163008; called by muse, mutect2, varscan2
- OR51D1 | c.480T>A p.S160= | Silent (SNP) | VAF 126/268 reads (47%) | catalogued as COSV62914142; called by muse, mutect2, varscan2
- OR51T1 | c.123C>G p.L41= | Silent (SNP) | VAF 101/264 reads (38%) | catalogued as COSV59025211; called by muse, mutect2, varscan2
- PDGFA | c.279C>T p.P93= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs781476779, COSV63279604; called by muse, mutect2, varscan2
- RANBP6 | c.553T>C p.L185= | Silent (SNP) | VAF 69/160 reads (43%) | catalogued as COSV52389226; called by muse, mutect2, varscan2
- SECISBP2L | c.174C>T p.Y58= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as rs748718106, COSV55934149; called by muse, mutect2, varscan2
- SLC14A2 | c.1440C>T p.H480= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV54908768; called by muse, mutect2, varscan2
- SPAG17 | c.5580A>G p.P1860= | Silent (SNP) | VAF 31/41 reads (76%) | catalogued as COSV60458102; called by muse, mutect2, varscan2
- SRBD1 | c.1995A>T p.P665= | Silent (SNP) | VAF 77/139 reads (55%) | catalogued as rs940986758, COSV55398278; called by muse, mutect2, varscan2
- TECPR2 | c.3147G>C p.S1049= | Silent (SNP) | VAF 73/153 reads (48%) | catalogued as COSV63970317, COSV63970333; called by muse, mutect2, varscan2
- TRAV17 | c.186C>A p.G62= | Silent (SNP) | VAF 43/125 reads (34%) | called by muse, mutect2, varscan2
- TRIM10 | c.1077C>T p.G359= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs777580680, COSV64998801; called by muse, mutect2, varscan2
- TRIP6 | c.579G>T p.G193= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV51933184; called by muse, mutect2, varscan2
- TTN | c.24588G>T p.L8196= (on ENST00000591111; = p.L7269= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as COSV60031528; called by muse, mutect2, varscan2
- TXNRD2 | c.1519C>T p.L507= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as COSV68692051; called by muse, mutect2, varscan2
- UBE3B | c.2961C>T p.F987= | Silent (SNP) | VAF 22/209 reads (11%) | catalogued as rs369743781; called by muse, mutect2, varscan2
- VNN1 | c.897C>G p.L299= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV63389866; called by muse, mutect2, varscan2
- ZFPM2 | c.2412G>T p.T804= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs1427405086, COSV65872612, COSV65873438; called by muse, mutect2, varscan2
- ZNF99 | c.1149C>A p.A383= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as COSV68055644, COSV68055965; called by muse, mutect2, varscan2
- ZSCAN18 | c.1407C>T p.Y469= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1026091088, COSV53732766; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499111 A>G | 5'Flank (SNP) | VAF 76/134 reads (57%) | catalogued as rs756779978; called by muse, mutect2, varscan2
- HOXB4 | chr17:48579940 G>C | 5'Flank (SNP) | VAF 26/99 reads (26%) | catalogued as COSV60178331; called by muse, mutect2, varscan2
- MALAT1 | n.44dup | RNA (INS) | VAF 57/139 reads (41%) | called by mutect2, pindel, varscan2
- NDUFV1 | chr11:67604955 G>T | 5'Flank (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- NRXN3 | c.602-5387G>T | Intron (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99822451; called by muse, mutect2, varscan2
- PML | c.1710+915G>T | Intron (SNP) | VAF 60/152 reads (39%) | catalogued as COSV99168436; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1541G>T | RNA (SNP) | VAF 6/9 reads (67%) | called by muse, varscan2
